TCGA case TCGA-2G-AAF7 — Testicular Germ Cell Tumors (TCGA-TGCT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Germ Cell Neoplasms; Primary site: Testis. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/830e832d-9da2-40fa-a0df-a78a96f2ef64

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Netherlands; Age at index: 30 years; Year of birth: 1974; Vital status: Alive.

Diagnoses (3)
1. Seminoma, NOS (the primary disease): ICD-O-3 morphology code: 9061/3; ICD-10 code: C62.9; Tissue or organ of origin: Testis, NOS; Site of resection or biopsy: Testis, NOS; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 30.3 years (11,065 days); Year of diagnosis: 2004; Method of diagnosis: Orchiectomy; AJCC staging edition: 6th; AJCC clinical T: T1; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage IS; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 3,880 days (10.6 years); Ajcc serum tumor markers: S2; Sites of involvement: Rete Testis.
   Pathology details: Intratubular germ cell neoplasia present: No; Lymphatic invasion present: No; Vascular invasion present: No.
   Pathology details: Lymph node dissection site: Retroperitoneal; Lymph nodes removed: No; Timepoint category: Postoperative.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 51 days; Days to treatment end: 68 days; Treatment dose: 26 Gy; Treatment outcome: Complete Response; Number of fractions: 13; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 2,840 days (7.8 years); Days to treatment end: 2,840 days (7.8 years); Treatment outcome: Complete Response.
   Treatment given: Treatment type: Surgery, NOS; Treatment anatomic sites: Testis.
2. Subsequent primary of the testis (histology not recorded by GDC). Age at diagnosis: 38.0 years (13,871 days); Days to diagnosis: 2,806 days (7.7 years); Prior treatment: Yes.
3. Subsequent primary of the testis (histology not recorded by GDC). Laterality: Bilateral; Age at diagnosis: 38.0 years (13,871 days); Days to diagnosis: 2,806 days (7.7 years).

Follow-up (4 entries)
- Days to follow up: 3,343 days (9.2 years); Disease response: Tumor Free.
- Days to follow up: 3,525 days (9.7 years); Disease response: Tumor Free.
- Days to follow up: 3,880 days (10.6 years); Disease response: Tumor Free.
- Karnofsky performance status: 100; ECOG performance status: 0; Timepoint: Follow-up.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day -4: Lactate Dehydrogenase 1073; Alpha Fetoprotein 0.9; Human Chorionic Gonadotropin 134.
- Day 51: Lactate Dehydrogenase 185; Alpha Fetoprotein 1; Human Chorionic Gonadotropin 0.7.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Fertility history: Did not attempt to reproduce; Undescended testis history: No.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-2G-AAF7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 210 mg.
  Slide TCGA-2G-AAF7-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 90; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 0.
- Sample TCGA-2G-AAF7-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-2G-AAF7-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
